Somatic mutation profile of tumor specimen TCGA-ER-A1A1-06A (aliquot TCGA-ER-A1A1-06A-11D-A197-08) from TCGA case TCGA-ER-A1A1, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 58.2 years (21,256 days).
Specimen TCGA-ER-A1A1-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8e06662-b763-4db5-8975-69b8a3063c03.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ER-A1A1-10A (Blood Derived Normal), aliquot TCGA-ER-A1A1-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99a65ca2-c539-4b0a-9c2a-600a4440f594

The open-access MAF lists 59 somatic variants for this specimen: 42 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 16, Splice Site 3, Intron 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC6 | c.3178C>T p.P1060S | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1447101816; called by mutect2, varscan2
- ALAD | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); catalogued as COSV52959428; called by muse, mutect2, varscan2
- BIRC6 | c.13211C>T p.S4404F | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.622); catalogued as COSV70201525; called by muse, mutect2
- BPIFC | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as COSV55913226; called by muse, mutect2, varscan2
- CDC45 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 44/230 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.18); catalogued as rs768226051, COSV54246352; called by mutect2, varscan2
- CNST | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as COSV63620640; called by muse, mutect2
- CRISPLD2 | c.1055G>A p.R352K | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV52280476; called by muse, mutect2
- CRYBA4 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as rs749003359, COSV61322253; called by mutect2, varscan2
- CYLC1 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.135); catalogued as COSV61413154; called by mutect2, varscan2
- DEFA3 | c.176-1G>A p.X59_splice | Splice Site (SNP) | VAF 8/119 reads (7%) | catalogued as rs1178958375; called by muse, mutect2
- DNAH5 | c.10354G>A p.D3452N | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.056); catalogued as COSV54234331; called by muse, mutect2
- FAM71B | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV57229681; called by muse, mutect2
- FAT3 | c.1052G>A p.G351E | Missense Mutation (SNP) | VAF 20/420 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53094924, COSV53130509; called by muse, mutect2
- FLG2 | c.6364T>C p.S2122P | Missense Mutation (SNP) | VAF 11/353 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV66169758; called by muse, mutect2
- GRIA2 | c.1622C>T p.P541L | Missense Mutation (SNP) | VAF 11/188 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV52395161; called by muse, mutect2
- HTRA4 | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 11/172 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56759834; called by muse, mutect2
- IGLV1-44 | c.181G>A p.G61R | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs1306224985; called by muse, mutect2
- KALRN | c.1087-1G>A p.X363_splice | Splice Site (SNP) | VAF 10/126 reads (8%) | catalogued as COSV53769704; called by muse, mutect2
- KMT2E | c.3254G>A p.R1085K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs1562932185, COSV57575667; called by muse, mutect2
- MAGEA6 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs1474857032, COSV61449127; called by muse, mutect2
- MXRA5 | c.2492C>T p.P831L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.21); catalogued as rs1405395209, COSV54225698; called by muse, mutect2
- MYH2 | c.2950C>T p.L984F | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as COSV55440539, COSV55441194; called by muse, mutect2
- MYH8 | c.5282C>T p.A1761V | Missense Mutation (SNP) | VAF 13/183 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV67967466; called by muse, mutect2
- NF2 | c.516G>A p.R172= | Splice Region (SNP) | VAF 8/122 reads (7%) | catalogued as COSV58525605; called by muse, mutect2
- NRK | c.1210C>T p.Q404* | Nonsense Mutation (SNP) | VAF 5/32 reads (16%) | catalogued as COSV54599524; called by muse, mutect2, varscan2
- OPN1LW | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100885078, COSV64049436; called by muse, mutect2, varscan2
- OR2A12 | c.701G>A p.R234K | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.03); catalogued as rs1389696357, COSV68821668; called by muse, mutect2
- OR2A2 | c.589G>A p.V197I | Missense Mutation (SNP) | VAF 13/207 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as COSV68871853; called by muse, mutect2
- PRKAG3 | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as rs947400938, COSV52102413; called by muse, mutect2
- RFPL3 | c.443G>A p.R148Q (on ENST00000249007 / NM_001098535.1; = p.R119Q on NM_006604.2) | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.242); catalogued as rs746530586, COSV50750179; called by mutect2, varscan2
- ST7 | c.1681T>C p.C561R | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); catalogued as COSV55387280; called by muse, mutect2
- SYN3 | c.26C>T p.S9F | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60510604; called by muse, mutect2, varscan2
- TACR3 | c.1124C>T p.P375L | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs867125460, COSV59203276; called by muse, mutect2
- TMEM108 | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 20/308 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.982); catalogued as COSV100419508; called by muse, mutect2
- TMIGD1 | c.443A>G p.N148S | Missense Mutation (SNP) | VAF 10/181 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61028674; called by muse, mutect2
- TRAF6 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV61922796; called by muse, mutect2, varscan2
- TUBGCP3 | c.1415C>T p.P472L | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV56188114; called by muse, mutect2
- WEE2 | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 13/188 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as COSV66879372; called by muse, mutect2
- MAGEA4 | c.636G>A p.M212I | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by mutect2, varscan2
- MAGEB6B | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRBV3-1 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.005); called by muse, mutect2
- ZNF827 | c.3053-1G>A p.X1018_splice | Splice Site (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- ARHGEF25 | c.1701C>T p.P567= | Silent (SNP) | VAF 10/176 reads (6%) | catalogued as COSV54087645; called by muse, mutect2
- ARSF | c.618G>A p.G206= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as rs777293098, COSV63839587; called by mutect2, varscan2
- CC2D1B | c.855C>T p.S285= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs769467299, COSV99430231; called by muse, mutect2, varscan2
- CELSR2 | c.768C>T p.V256= | Silent (SNP) | VAF 16/254 reads (6%) | catalogued as COSV54774384; called by muse, mutect2
- EGFL6 | c.585T>C p.F195= | Silent (SNP) | VAF 7/74 reads (9%) | catalogued as COSV63634309; called by muse, mutect2
- HAPLN3 | c.165G>A p.E55= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as COSV62085506; called by muse, mutect2
- HEXD | c.768G>A p.K256= | Silent (SNP) | VAF 12/122 reads (10%) | catalogued as COSV60064308, COSV60064570; called by muse, mutect2
- KMT2E | c.3255G>A p.R1085= | Silent (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- LAMB4 | c.4953G>A p.Q1651= | Silent (SNP) | VAF 16/178 reads (9%) | catalogued as COSV52721541; called by muse, mutect2
- PASD1 | c.1138T>C p.L380= | Silent (SNP) | VAF 6/125 reads (5%) | catalogued as COSV64855915; called by muse, mutect2
- ROS1 | c.2871G>A p.R957= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs191810593, COSV63856876; called by mutect2, varscan2
- SEPHS2 | c.1152T>G p.A384= | Silent (SNP) | VAF 7/82 reads (9%) | catalogued as COSV72100776; called by muse, mutect2
- SLC35F4 | c.294C>T p.S98= (on ENST00000339762 / NM_001352015.2; = p.S62= on NM_001206920.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV60262872, COSV60265464; called by mutect2, varscan2
- SLITRK4 | c.408C>T p.L136= | Silent (SNP) | VAF 9/102 reads (9%) | catalogued as COSV100567486; called by muse, mutect2
- SYNGAP1 | c.3699C>T p.I1233= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV53382825; called by muse, mutect2, varscan2
- TRGC1 | c.180G>A p.G60= | Silent (SNP) | VAF 12/211 reads (6%) | called by muse, mutect2
- MAP3K19 | c.3222+401A>G | Intron (SNP) | VAF 10/137 reads (7%) | catalogued as COSV100209135; called by muse, mutect2
